Surgical pathology report (de-identified scan), TCGA case TCGA-64-1678, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-1678-01A (Primary Tumor).

[page 1 of 5]
Clinical History/Diagnosis: Lung CA

Source of Specimen(s):

- 1: 4R lymph nodes
- 2: Additional 4R lymph nodes
- 3: Additional 4R lymph nodes
- 4: Level 7 lymph nodes
- 5: 4L lymph nodes
- 6: 4R lymph node
- 7: 2R lymph nodes
- 8: Level 11 lymph nodes
- 9: 10R lymph node
- 10: right middle lobe
- 11: 11R lymph nodes

Gross Description:

Received in eleven parts.

Source of Tissue: 1. Labeled # 1, "4R lymph nodes"

Frozen Section Diagnosis: 1FS- NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation labeled "patient name and medical number, 4R lymph nodes" are 1.5 x 1.0 x 0.4 cm of gray-black anthracotic stained lymph node fragments. They are submitted in toto for frozen section evaluation and the frozen itself was submitted in one block.

Designation of Sections: 1FS

Summary of Sections: FS-multiple

Source of Tissue: 2. Labeled # 2, "additional 4R nodes"

Frozen Section Diagnosis: 2FS- NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation labeled "patient name and medical number, additional 4R nodes" are 1.5 x 1.0 x 0.4 cm of gray-black anthracotic stained lymph node fragments. They are submitted in toto for frozen section evaluation and the frozen itself was submitted in one block.

[page 2 of 5]
Designation of Sections: 2FS

Summary of Sections: FS-multiple

Source of Tissue: 3. Labeled # 3, "additional 4R lymph nodes"

Frozen Section Diagnosis: 3FS- NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation labeled " patient name and medical number, additional 4R lymph nodes" are 1.0 x 0.8 x 0.4 cm of gray-black anthracotic stained lymph node fragments. They are submitted in toto for frozen section evaluation and the frozen itself was submitted in one block.

Designation of Sections: 3FS

Summary of Sections: FS-multiple

Source of Tissue: 4. Labeled # 4, "level 7 lymph nodes"

Frozen Section Diagnosis: 4FS- NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation labeled " patient name and medical number, level 7 lymph nodes" are 1.5 x 1.5 x 0.4 cm of gray-black anthracotic stained lymph node fragments. They are submitted in toto for frozen section evaluation and the frozen itself was submitted in one block.

Designation of Sections: 4FS

Summary of Sections: FS-multiple

Source of Tissue: 5. Labeled # 5, "4L lymph nodes"

Frozen Section Diagnosis: 5FS- NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation labeled " patient name and medical number, 4L lymph nodes" are 0.6 x 0.5 x 0.3 cm of gray-black anthracotic stained tissue fragments. They are submitted in toto for frozen section evaluation and the frozen itself was submitted in one block.

Designation of Sections: 5FS

[page 3 of 5]
Summary of Sections: FS-multiple

Source of Tissue: 6. Labeled # 6, "4R lymph node"

Gross Description: Received fresh labeled " patient name and medical number, 4R lymph node" is a 0.5 cm gray-black anthracotic stained tissue fragment which is submitted in toto in one block.

Designation of Sections: block 6

Summary of Sections: undesignated-1

Source of Tissue: 7. Labeled # 7, "2R lymph nodes"

Frozen Section Diagnosis: 7FS- NO TUMOR SEEN.

Gross Description: Received fresh for frozen section evaluation labeled " patient name and medical number, 2R lymph nodes" are 1.5 x 1.0 x 0.4 cm of gray-black anthracotic stained lymph node fragments. They are submitted in toto for frozen section evaluation and the frozen itself was submitted in one block.

Designation of Sections: 7FS

Summary of Sections: FS-multiple

Source of Tissue: 8. Labeled # 8, "level 11 lymph nodes"

Gross Description: Received fresh labeled " patient name and medical number, level 11 lymph nodes" are 1.0 x 0.8 x 0.3 cm of red-purple to gray-black anthracotic stained tissue fragments. They are submitted in toto in one block.

Designation of Sections: block 8

Summary of Sections: undesignated-multiple

Source of Tissue: 9. Labeled # 9, "10R lymph node"

Gross Description: Received fresh labeled " patient name and medical number, 10R lymph node" is a 1.4 cm in greatest dimension gray-black anthracotic

[page 4 of 5]
stained lymph node which is entirely submitted in one block.

Designation of Sections: block 9

Summary of Sections: undesignated-2

Source of Tissue: 10. Labeled #10, "right middle lobe"

Frozen Section Diagnosis: 10FS- BRONCHIAL MARGIN IS NEGATIVE FOR TUMOR.

Gross Description: Received fresh for frozen section consultation labeled " patient name and medical number, right middle lobe". It consists of a 120 gram right middle lobe of lung measuring 10.5 x 8.5 x 5.5 cm. The bronchial margin is procured for frozen section and the residue is in 10FS. Elsewhere the pleura has a large smooth indurated area with a few dark red adhesions and large palpable mass in the specimen. The vascular margins are grossly unremarkable. Opening of the bronchial tree discloses tumor coming to within 1.0 cm from the margin and a few dark black hilar nodes measuring up to 0.8 cm. There is a large right middle lobe lung tumor measuring 6.0 x 6.0 x 4.5 cm occupying approximately 30% of the middle lobe. Representative sections are submitted 10A-G.

Designation of Sections: 10A- vascular margins, 10B- peribronchial lymph nodes, 10C-10D- tumor in relationship to bronchial tree, 1.0 cm from hilum, 10E- tumor in relationship to adjacent parenchyma, 10F- tumor in relationship to pleura, 10G- uninvolved lung

Source of Tissue: 11. Labeled # 11, "11R lymph node"

Gross Description: Received fresh labeled " patient name and medical number, 11R lymph node" are 1.0 x 0.8 x 0.4 cm of gray-black anthracotic stained tissue fragments. They are submitted in toto in one block.

Designation of Sections: block 11

Summary of Sections: undesignated-multiple

Final Diagnosis:

1. 4R lymph nodes, biopsy:
- No tumor seen in four lymph nodes (0/4).
2. Lymph nodes, additional 4R, biopsy:
- No tumor seen in four lymph nodes (0/4).

[page 5 of 5]
3. Lymph nodes, additional 4R, biopsy:
- No tumor seen in two lymph nodes (0/2).

4. Lymph nodes, level 7, biopsy:
No tumor seen in six lymph nodes (0/6).

5. Lymph nodes, 4L, biopsy:
- No tumor seen in two lymph nodes (0/2).

6. Lymph node, 4R, biopsy:
- One lymph node, no tumor seen (0/1).

7. Lymph nodes, 2R, biopsy:
- No tumor seen in four lymph nodes (0/4).

8. Lymph nodes, level 11, biopsy:
- No tumor seen in four lymph nodes (0/4).

9. Lymph node 10R, biopsy:
- No tumor seen in four lymph nodes (0/4).

10. Lung, right middle lobe, lobectomy:
- Poorly differentiated adenocarcinoma (6 cm); no visceral pleural invasion seen; lymphovascular space invasion is not seen.
- Bronchial and vascular margins are free of tumor.
- Three peribronchial lymph nodes with no tumor seen (0/3).

(pT2NoMx)

Source: NCI Genomic Data Commons file deba1751-03e1-4c5b-95ad-05aeab655d88 (TCGA-64-1678.5B49E9B0-C7F5-43A2-9D48-34C1537C148D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).